Somatic mutation profile of tumor specimen TCGA-DB-5278-01A (aliquot TCGA-DB-5278-01A-01D-1468-08) from TCGA case TCGA-DB-5278, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 17.7 years (6,480 days).
Specimen TCGA-DB-5278-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49f9f2ce-4b25-4586-9c8a-c0f5fc53ea4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5278-10A (Blood Derived Normal), aliquot TCGA-DB-5278-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bd513b6-3588-41d7-bf0c-f90a81c1f017

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 52/133 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CIC | c.629T>G p.F210C | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50559402; called by muse, mutect2, varscan2
- RAB3GAP2 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as rs371630366; called by muse, mutect2, varscan2
- SLC7A9 | c.115A>C p.I39L | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV50084150; called by muse, mutect2, varscan2
- SVIL | c.5097C>A p.H1699Q (on ENST00000355867 / NM_021738.3; = p.H1273Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 216/640 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63442500; called by muse, mutect2, varscan2
- DAZAP1 | c.693C>T p.G231= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
